Somatic mutation profile of tumor specimen MP2PRT-PAVMAK-TMP1-A (aliquot MP2PRT-PAVMAK-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVMAK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (843 days).
Specimen MP2PRT-PAVMAK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58a2b67a-2610-498d-8400-9ec92d928ba1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMAK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMAK-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7ffe92c-4b0e-472e-ab62-f4a6b01404f7

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 133/253 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CAPN1 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 41/499 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs763471308, COSV54198268; ClinVar: uncertain significance; called by muse, mutect2
- CADPS2 | c.1155T>G p.I385M | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- SLITRK3 | c.2438A>G p.E813G | Missense Mutation (SNP) | VAF 29/343 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- FGF14 | c.6C>T p.A2= | Silent (SNP) | VAF 119/381 reads (31%) | catalogued as rs550680103; called by muse, mutect2, varscan2
- GPR25 | c.66C>T p.D22= | Silent (SNP) | VAF 22/480 reads (5%) | catalogued as rs1367321786; called by muse, mutect2
- SRP68 | c.1440C>T p.S480= | Silent (SNP) | VAF 52/185 reads (28%) | catalogued as rs751426983; called by muse, mutect2, varscan2
- ZC3H11B | c.876C>T p.G292= | Silent (SNP) | VAF 86/321 reads (27%) | catalogued as rs537343519; called by muse, mutect2, varscan2
